Somatic mutation profile of tumor specimen TCGA-AC-A3OD-01B (aliquot TCGA-AC-A3OD-01B-06D-A22N-09) from TCGA case TCGA-AC-A3OD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.0 years (25,186 days).
Specimen TCGA-AC-A3OD-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40b0cf38-d0a2-466c-8b28-e541b4ea8991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A3OD-10A (Blood Derived Normal), aliquot TCGA-AC-A3OD-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba648584-9909-4fd1-87d9-75757e1872eb

The open-access MAF lists 18 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Nonsense Mutation 3, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs587782750, COSV55729418; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ECPAS | c.3157G>T p.D1053Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99398246; called by muse, varscan2
- FATE1 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs758256359, COSV64849270; called by muse, mutect2, varscan2
- HYDIN | c.13148G>A p.R4383Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368513191; called by muse, mutect2, varscan2
- KCNF1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV54465292; called by muse, varscan2
- MAGEB16 | c.927T>G p.Y309* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV67874450; called by mutect2, varscan2
- PCDH11X | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs1161362870, COSV100011655; called by muse, mutect2, varscan2
- POLR3D | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60572069; called by muse, mutect2, varscan2
- PPP6R3 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV55734711; called by muse, mutect2, varscan2
- RNF40 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.373); catalogued as rs751674221, COSV61216402; called by muse, mutect2, varscan2
- SF1 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV99918306; called by muse, mutect2
- TIMP1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV54483811; called by muse, mutect2, varscan2
- ZSWIM2 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54578824; called by muse, mutect2, varscan2
- CHUK | c.2167_2168del p.I723Yfs*3 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- RGS7 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- SRPRA | c.1414T>C p.L472= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs761323833, COSV55008615; called by muse, mutect2, varscan2
